Somatic mutation profile of tumor specimen 0DWNTL from CCDI case PBCNNP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.1 years (4,423 days).
Specimen 0DWNTL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0db97b66-f190-4317-bcfc-68e4e77c73c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWNQZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f48be0fd-72e5-44dc-b134-b193d88acaf5

The open-access MAF lists 24 somatic variants for this specimen: 16 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 5, Intron 1, In Frame Del 1, Frame Shift Del 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 199/597 reads (33%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1727_1729del p.T576del (on ENST00000521381 / NM_181523.3; = p.T306del on NM_181504.4) | In Frame Del (DEL) | VAF 319/926 reads (34%) | hotspot (GDC flag); catalogued as rs1057519842; ClinVar: likely pathogenic; called by mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 394/478 reads (82%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC11 | c.4111G>A p.A1371T | Missense Mutation (SNP) | VAF 232/535 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs139034695, COSV62324823; called by muse, mutect2, varscan2
- ATRX | c.5263C>G p.L1755V | Missense Mutation (SNP) | VAF 182/516 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100971430, COSV64875446; called by muse, mutect2, varscan2
- MED12L | c.221G>A p.S74N | Missense Mutation (SNP) | VAF 263/729 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0.229); catalogued as COSV99853823; called by muse, mutect2, varscan2
- MORC4 | c.58C>T p.R20W | Missense Mutation (SNP) | VAF 137/361 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs1237287621; called by muse, mutect2, varscan2
- SLX4 | c.4393C>T p.R1465C | Missense Mutation (SNP) | VAF 180/506 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs765485426, COSV53561837; called by muse, mutect2, varscan2
- TTC33 | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 290/1160 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.933); catalogued as rs139469375, COSV61802570; called by muse, mutect2, varscan2
- AMBRA1 | c.2749del p.D917Mfs*31 (on ENST00000458649 / NM_001367468.1; = p.D827Mfs*31 on NM_017749.3 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 155/431 reads (36%) | called by mutect2, varscan2
- DAAM1 | c.328C>T p.L110F | Missense Mutation (SNP) | VAF 212/575 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- HDX | c.1996C>A p.H666N | Missense Mutation (SNP) | VAF 373/997 reads (37%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- IKZF2 | c.1163G>T p.R388I | Missense Mutation (SNP) | VAF 318/759 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IRAK1 | c.1672G>T p.A558S | Missense Mutation (SNP) | VAF 139/351 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- LUC7L2 | c.1133C>T p.S378L | Missense Mutation (SNP) | VAF 332/870 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- MYT1 | c.2261C>G p.S754C | Missense Mutation (SNP) | VAF 337/840 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- BCORL1 | c.4677T>C p.F1559= | Silent (SNP) | VAF 130/821 reads (16%) | called by muse, mutect2, varscan2
- CHST15 | c.1242C>T p.D414= | Silent (SNP) | VAF 213/589 reads (36%) | called by muse, mutect2, varscan2
- GRIK2 | c.384C>G p.P128= | Silent (SNP) | VAF 58/988 reads (6%) | called by muse, mutect2
- REG1B | c.381A>T p.G127= | Silent (SNP) | VAF 357/933 reads (38%) | catalogued as rs771205141; called by muse, mutect2, varscan2
- UGT2B17 | c.51C>T p.Y17= | Silent (SNP) | VAF 320/419 reads (76%) | called by muse, mutect2, varscan2
- CNTN2 | c.798-60G>C | Intron (SNP) | VAF 49/117 reads (42%) | called by muse, mutect2
- GAB3 | chrX:154751064 G>A | 5'Flank (SNP) | VAF 69/183 reads (38%) | called by muse, mutect2, varscan2
- ZCRB1 | c.*83T>A | 3'UTR (SNP) | VAF 58/221 reads (26%) | catalogued as COSV99861273; called by muse, mutect2, varscan2
